Somatic mutation profile of tumor specimen C3N-00874-01 (aliquot CPT0078430010) from CPTAC case C3N-00874, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 56.2 years (20,511 days).
Specimen C3N-00874-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28f58a73-9811-4913-bb7a-f085cf670132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00874-31 (Blood Derived Normal), aliquot CPT0078470008; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1caa4ec-be90-4b06-9237-137166f1dadc

The open-access MAF lists 203 somatic variants for this specimen: 128 protein-altering or splice-affecting, 63 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 63, Intron 6, Nonsense Mutation 5, Splice Site 2, RNA 2, 5'UTR 1, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 81/265 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs63083560, CM068056; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- ADAM18 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV55853554; called by muse, mutect2, varscan2
- ADAM7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 132/406 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99443322; called by muse, mutect2, varscan2
- ADAMTS2 | c.2429G>A p.G810D | Missense Mutation (SNP) | VAF 127/363 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1249468826; called by muse, varscan2
- APAF1 | c.2414C>T p.S805L (on ENST00000551964 / NM_181861.2; = p.S794L on NM_001160.3) | Missense Mutation (SNP) | VAF 125/358 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs375207439; called by muse, mutect2, varscan2
- ARHGEF2 | c.1321C>T p.R441C (on ENST00000361247 / NM_001162383.2; = p.R413C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/511 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1281348315, COSV58109762; called by muse, mutect2, varscan2
- C10orf71 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV60510865; called by muse, mutect2, varscan2
- CCDC102B | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs369503833; called by muse, mutect2, varscan2
- CFAP52 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1361072712, COSV55343747; called by muse, mutect2, varscan2
- CNGB1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 180/373 reads (48%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.636); catalogued as rs549685470; called by muse, mutect2, varscan2
- CPEB1 | c.661C>T p.P221S (on ENST00000617958; = p.P161S on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/484 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.046); catalogued as rs751930618; called by muse, mutect2, varscan2
- CRISP3 | c.644C>T p.P215L (on ENST00000371159 / NM_001368123.1; = p.P197L on NM_006061.4) | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978640914; called by muse, mutect2, varscan2
- CSMD1 | c.10294G>A p.D3432N (on ENST00000520002; = p.D3431N on NM_033225.6) | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs762371826; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 153/432 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DCLK3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs746230526, COSV69362234; called by muse, mutect2
- DNAH2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as rs753334898, COSV50014965; called by muse, mutect2, varscan2
- DSC1 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs865860727, COSV99937673; called by muse, mutect2, varscan2
- DSG4 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs372042028; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.964); catalogued as COSV62568739; called by muse, mutect2, varscan2
- ENAH | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1344761260; called by muse, mutect2, varscan2
- F13A1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 180/671 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); catalogued as rs767358574, COSV53553578, COSV99343451; called by muse, mutect2, varscan2
- FAM151A | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 123/609 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs1289718925; called by muse, mutect2, varscan2
- FLNC | c.6695G>A p.G2232E | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1401495485; called by muse, mutect2, varscan2
- FURIN | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs528245274; called by muse, mutect2, varscan2
- GOLGB1 | c.1924A>G p.T642A | Missense Mutation (SNP) | VAF 121/339 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as rs200572870; called by muse, mutect2, varscan2
- GPRC6A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.783); catalogued as COSV100114240; called by muse, mutect2, varscan2
- GRIK2 | c.1333C>T p.L445F | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1351645179, COSV59730742; called by muse, mutect2, varscan2
- HAPLN4 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 171/468 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs868748770, COSV52269289; called by muse, mutect2, varscan2
- HCN1 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 140/355 reads (39%) | catalogued as COSV100299760; called by muse, mutect2, varscan2
- IL20RA | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 141/365 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs867071878; called by muse, mutect2, varscan2
- ISM2 | c.655dup p.Q219Pfs*11 | Frame Shift Ins (INS) | VAF 111/365 reads (30%) | catalogued as rs1264686266; called by mutect2, pindel, varscan2
- ITGA9 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53255650; called by muse, mutect2, varscan2
- KIF21A | c.3638C>T p.P1213L (on ENST00000361418 / NM_001378440.1; = p.P1200L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs866768006; called by muse, mutect2, varscan2
- MCTP2 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 149/468 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as COSV100537573; called by muse, mutect2
- ME3 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 149/465 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs1248755132; called by muse, mutect2, varscan2
- MEGF10 | c.781-1G>A p.X261_splice | Splice Site (SNP) | VAF 67/213 reads (31%) | catalogued as COSV57245890; called by muse, mutect2, varscan2
- MUSK | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 107/282 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV51891678; called by muse, mutect2, varscan2
- MYH2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1389727909, COSV55435196; called by muse, mutect2, varscan2
- MYT1L | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs556030125, COSV67710792; called by muse, mutect2, varscan2
- NLRP11 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV64087763; called by muse, mutect2, varscan2
- NR1H4 | c.763-1G>A p.X255_splice (on ENST00000551379 / NM_001206993.2; = p.X241_splice on NM_005123.4) | Splice Site (SNP) | VAF 50/204 reads (25%) | catalogued as COSV51849951; called by muse, mutect2, varscan2
- OR1J2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.044); catalogued as COSV58945228; called by muse, mutect2, varscan2
- OR8D2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 125/352 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1379045399, COSV100658935; called by muse, mutect2, varscan2
- PCLO | c.6442G>A p.D2148N | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs374966632; called by muse, mutect2, varscan2
- PDE1B | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs764032346, COSV54495233; called by muse, mutect2, varscan2
- PIKFYVE | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100009944; called by muse, mutect2, varscan2
- PKHD1L1 | c.5797G>A p.E1933K | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as COSV65747007; called by muse, mutect2, varscan2
- POLK | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.571); catalogued as COSV54033942; called by muse, mutect2, varscan2
- PRICKLE1 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs760050261, CM119662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTGR2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 94/235 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV50866706; called by muse, mutect2, varscan2
- RGPD4 | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs1375706007, COSV100736568; called by muse, mutect2, varscan2
- SAMD9L | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs867794849, COSV59083226; called by muse, mutect2, varscan2
- SCN10A | c.4774G>A p.G1592R | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs866103882, COSV71860409; called by muse, mutect2, varscan2
- SCN3A | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs759125218; called by muse, mutect2, varscan2
- SEZ6L | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.427); catalogued as rs760398959, COSV50690159; called by muse, mutect2, varscan2
- SI | c.3905G>A p.G1302E | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014545; called by muse, mutect2, varscan2
- SLC28A2 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100754681; called by muse, mutect2, varscan2
- SLC6A4 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 137/370 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55566498; called by muse, mutect2, varscan2
- SMARCA4 | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867713307, COSV60804408; called by muse, mutect2
- SMPD1 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 99/328 reads (30%) | catalogued as CM023152; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 141/392 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100561681; called by muse, mutect2, varscan2
- SULT1C3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs866697546, COSV61252236; called by muse, mutect2, varscan2
- TAF5 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 116/333 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100428263; called by muse, mutect2, varscan2
- THBS1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.168); catalogued as COSV99527914; called by muse, mutect2, varscan2
- TMEM87B | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs769088454, COSV51718572; called by muse, mutect2, varscan2
- TTC23 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as rs1355290815; called by muse, mutect2, varscan2
- USH2A | c.8734C>T p.P2912S | Missense Mutation (SNP) | VAF 115/452 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100244282; called by muse, mutect2, varscan2
- UTP23 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 112/443 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752871869, COSV59124306; called by muse, mutect2, varscan2
- VWF | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 112/370 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs150418484; called by muse, mutect2, varscan2
- ZFHX4 | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs917060953, COSV51450351; called by muse, mutect2, varscan2
- ZNF385B | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 135/367 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61175752; called by muse, mutect2, varscan2
- ZNF775 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61613751; called by muse, mutect2, varscan2
- AKAP5 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 161/402 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA7 | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 108/327 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP1A1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 103/401 reads (26%) | called by muse, mutect2, varscan2
- C4orf50 | c.83T>G p.L28R (on ENST00000324058; = p.L1260R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1E | c.4118G>A p.G1373E | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN14 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 120/402 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2
- CHERP | c.1973T>G p.L658R | Missense Mutation (SNP) | VAF 101/336 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CHGB | c.549T>G p.S183R | Missense Mutation (SNP) | VAF 116/300 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); called by muse, varscan2
- COL5A1 | c.4423G>A p.D1475N | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CTNNA3 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- CYBB | c.949T>C p.F317L | Missense Mutation (SNP) | VAF 147/225 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH10 | c.2123C>T p.S708F (on ENST00000409039; = p.S647F on NM_207437.3) | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DNAH14 | c.1166T>C p.V389A (on ENST00000445597; = p.V370A on NM_001145154.3) | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- DNAH17 | c.11570G>A p.G3857D | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DNAJB12 | c.551C>T p.A184V (on ENST00000338820; = p.A150V on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DST | c.9225T>G p.N3075K | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELOA3C | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 58/1257 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.015); called by muse, mutect2
- FAM214B | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 133/384 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GALNT9 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 99/314 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GJA1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 112/329 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- GLT1D1 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HGF | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HMX1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 187/511 reads (37%) | called by muse, mutect2, varscan2
- IFT172 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- IK | c.1071_1082del p.E359_R362del | In Frame Del (DEL) | VAF 93/356 reads (26%) | called by mutect2, pindel, varscan2
- MARCOL | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLIP | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- MYT1L | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- NPAP1 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 172/437 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- OR1L1 | c.536C>T p.P179L (on ENST00000373686; = p.P129L on NM_001005236.3) | Missense Mutation (SNP) | VAF 138/369 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- PAX2 | c.946G>A p.G316S (on ENST00000428433 / NM_003987.5; = p.G293S on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- PDE3B | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PITX2 | c.889G>T p.A297S (on ENST00000354925 / NM_001204397.1; = p.A304S on NM_000325.6) | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0.02); called by mutect2, varscan2
- PLCH1 | c.3317A>T p.K1106I (on ENST00000340059 / NM_001130960.2; = p.K1098I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/348 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLCH1 | c.463G>A p.D155N (on ENST00000340059 / NM_001130960.2; = p.D167N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF6 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2
- RAB27B | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RTL10 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- SCAF4 | c.1733C>G p.A578G | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SH3TC1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); called by muse, varscan2
- SLC16A12 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 140/388 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SOX2 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 193/569 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPATA31A1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 183/515 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TDRD15 | c.4253C>T p.P1418L | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD15 | c.4712C>T p.S1571L | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TMEM72 | c.248A>T p.K83I | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TNFSF18 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOM1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TRPC4 | c.236A>T p.E79V | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- UBE4A | c.807G>T p.M269I (on ENST00000252108 / NM_001204077.2; = p.M276I on NM_004788.4) | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP17L22 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 52/2260 reads (2%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- VGF | c.53A>C p.N18T | Missense Mutation (SNP) | VAF 142/429 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- YTHDF1 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 149/407 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFPM2 | c.2515C>T p.Q839* | Nonsense Mutation (SNP) | VAF 153/519 reads (29%) | called by muse, mutect2, varscan2
- ZSCAN30 | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM3 | c.1497A>G p.E499= | Silent (SNP) | VAF 94/251 reads (37%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.1011C>T p.I337= | Silent (SNP) | VAF 88/310 reads (28%) | catalogued as rs773003821, COSV57297073; called by muse, mutect2, varscan2
- ADGRB3 | c.1768C>T p.L590= | Silent (SNP) | VAF 77/287 reads (27%) | catalogued as rs753139957, COSV65388657; called by muse, mutect2, varscan2
- ALDH1A2 | c.981C>T p.F327= | Silent (SNP) | VAF 133/377 reads (35%) | catalogued as rs774853794, COSV51079031; called by muse, mutect2, varscan2
- ALPK2 | c.4557G>A p.G1519= | Silent (SNP) | VAF 116/356 reads (33%) | catalogued as rs750398552; called by muse, mutect2, varscan2
- ANKS1B | c.78G>A p.R26= | Silent (SNP) | VAF 133/323 reads (41%) | catalogued as COSV100243893; called by muse, mutect2, varscan2
- B3GALT1 | c.420C>T p.I140= | Silent (SNP) | VAF 103/424 reads (24%) | catalogued as rs149194939, COSV59910016; called by muse, mutect2, varscan2
- CCDC170 | c.1461G>A p.Q487= | Silent (SNP) | VAF 80/231 reads (35%) | called by muse, mutect2, varscan2
- CD1A | c.249G>A p.L83= | Silent (SNP) | VAF 100/523 reads (19%) | called by muse, mutect2, varscan2
- CFTR | c.1036C>T p.L346= | Silent (SNP) | VAF 74/288 reads (26%) | catalogued as rs575762281; called by muse, mutect2, varscan2
- CHRNB2 | c.1152C>T p.A384= | Silent (SNP) | VAF 371/748 reads (50%) | catalogued as rs746495548; called by muse, mutect2, varscan2
- COL2A1 | c.3231C>T p.G1077= | Silent (SNP) | VAF 116/373 reads (31%) | catalogued as rs1258036068; called by muse, mutect2, varscan2
- CTAGE6 | c.879G>A p.L293= | Silent (SNP) | VAF 51/342 reads (15%) | catalogued as rs755221859; called by muse, mutect2, varscan2
- CYBB | c.693G>A p.Q231= | Silent (SNP) | VAF 80/119 reads (67%) | called by muse, mutect2, varscan2
- DENND2B | c.1359G>A p.E453= | Silent (SNP) | VAF 74/251 reads (29%) | called by muse, mutect2, varscan2
- DRD5 | c.45C>T p.F15= | Silent (SNP) | VAF 124/368 reads (34%) | catalogued as COSV58577321; called by muse, mutect2, varscan2
- EDA | c.54G>A p.R18= | Silent (SNP) | VAF 184/256 reads (72%) | called by muse, mutect2, varscan2
- EHMT2 | c.1702C>T p.L568= | Silent (SNP) | VAF 185/761 reads (24%) | called by muse, mutect2, varscan2
- ENPEP | c.2061G>A p.E687= | Silent (SNP) | VAF 90/276 reads (33%) | catalogued as COSV54456976; called by muse, mutect2, varscan2
- F2RL1 | c.636G>A p.V212= | Silent (SNP) | VAF 159/438 reads (36%) | called by muse, mutect2, varscan2
- FYN | c.1011C>T p.P337= | Silent (SNP) | VAF 100/307 reads (33%) | called by muse, mutect2, varscan2
- GALNT14 | c.1119C>T p.A373= | Silent (SNP) | VAF 97/307 reads (32%) | catalogued as rs768874660; called by muse, mutect2, varscan2
- GNAZ | c.936C>T p.N312= | Silent (SNP) | VAF 16/480 reads (3%) | called by muse, mutect2
- GOLGB1 | c.6135A>T p.L2045= | Silent (SNP) | VAF 64/226 reads (28%) | called by muse, mutect2, varscan2
- GSG1L2 | c.99G>A p.E33= | Silent (SNP) | VAF 192/550 reads (35%) | called by muse, mutect2, varscan2
- HABP2 | c.552G>A p.G184= | Silent (SNP) | VAF 93/253 reads (37%) | catalogued as COSV63637871; called by muse, mutect2, varscan2
- HDAC9 | c.2526C>T p.L842= | Silent (SNP) | VAF 86/288 reads (30%) | called by muse, mutect2, varscan2
- HEPHL1 | c.207G>A p.R69= | Silent (SNP) | VAF 65/241 reads (27%) | catalogued as rs758594442, COSV59897036; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 80/219 reads (37%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- MUC16 | c.38106C>T p.T12702= | Silent (SNP) | VAF 80/241 reads (33%) | catalogued as rs1427398760; called by muse, mutect2, varscan2
- MYO15A | c.4312C>T p.L1438= | Silent (SNP) | VAF 100/257 reads (39%) | called by muse, mutect2, varscan2
- MYRFL | c.1731T>C p.S577= | Silent (SNP) | VAF 104/300 reads (35%) | catalogued as rs1269609474; called by muse, mutect2, varscan2
- NLRP13 | c.1935C>T p.S645= | Silent (SNP) | VAF 173/484 reads (36%) | catalogued as rs1346656839; called by muse, mutect2, varscan2
- OBSCN | c.17907C>T p.F5969= | Silent (SNP) | VAF 260/495 reads (53%) | catalogued as rs1418529961, COSV52761583; called by muse, mutect2, varscan2
- OCA2 | c.2373C>T p.V791= | Silent (SNP) | VAF 100/329 reads (30%) | catalogued as rs761657884, CD051776, COSV62337428; called by muse, mutect2, varscan2
- OR51F1 | c.930G>A p.K310= | Silent (SNP) | VAF 110/299 reads (37%) | called by muse, mutect2, varscan2
- OR51V1 | c.282G>A p.E94= | Silent (SNP) | VAF 142/380 reads (37%) | called by muse, mutect2, varscan2
- OR52E1 | c.615G>A p.L205= | Silent (SNP) | VAF 86/272 reads (32%) | catalogued as rs762553640; called by muse, mutect2, varscan2
- PAH | c.615G>A p.E205= | Silent (SNP) | VAF 123/335 reads (37%) | catalogued as rs765552494, CM128146; called by muse, mutect2
- PAX1 | c.477C>T p.S159= | Silent (SNP) | VAF 75/455 reads (16%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1830G>A p.T610= | Silent (SNP) | VAF 46/972 reads (5%) | called by muse, mutect2
- PCDHB7 | c.1830G>A p.T610= | Silent (SNP) | VAF 186/1925 reads (10%) | catalogued as rs554758462, COSV99176764; called by muse, mutect2
- PDE1C | c.1632G>A p.E544= | Silent (SNP) | VAF 141/422 reads (33%) | catalogued as COSV58523511; called by muse, mutect2, varscan2
- POTEE | c.108G>A p.R36= | Silent (SNP) | VAF 157/472 reads (33%) | called by muse, mutect2, varscan2
- PPFIA2 | c.15G>A p.V5= | Silent (SNP) | VAF 78/247 reads (32%) | catalogued as rs979194760; called by muse, mutect2, varscan2
- S100A14 | c.45C>T p.F15= | Silent (SNP) | VAF 120/336 reads (36%) | called by muse, mutect2, varscan2
- SCN10A | c.4773G>A p.K1591= | Silent (SNP) | VAF 123/415 reads (30%) | catalogued as COSV101479476; called by muse, mutect2, varscan2
- SCN3A | c.519C>T p.I173= | Silent (SNP) | VAF 82/249 reads (33%) | called by muse, mutect2, varscan2
- SEPTIN5 | c.840C>T p.F280= | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as rs779266097, COSV63530406; called by muse, mutect2, varscan2
- SH3TC1 | c.300C>T p.P100= | Silent (SNP) | VAF 59/431 reads (14%) | catalogued as rs756260540, COSV99794359; called by muse, mutect2, varscan2
- SIGLEC14 | c.1110C>T p.F370= | Silent (SNP) | VAF 93/275 reads (34%) | called by muse, mutect2, varscan2
- SLC1A7 | c.1509C>T p.I503= | Silent (SNP) | VAF 341/600 reads (57%) | catalogued as rs972831062, COSV57016808, COSV57017139; called by muse, mutect2, varscan2
- SLC27A6 | c.354C>T p.F118= | Silent (SNP) | VAF 120/326 reads (37%) | catalogued as rs1372634243, COSV52479372; called by muse, mutect2, varscan2
- STON2 | c.153G>A p.G51= | Silent (SNP) | VAF 42/432 reads (10%) | catalogued as rs188287240; called by muse, mutect2
- TAS2R3 | c.618C>T p.S206= | Silent (SNP) | VAF 132/369 reads (36%) | catalogued as rs1204721249, COSV99924516; called by muse, mutect2, varscan2
- TCF7L1 | c.372C>T p.F124= | Silent (SNP) | VAF 91/282 reads (32%) | called by muse, mutect2, varscan2
- TERB2 | c.81G>A p.T27= | Silent (SNP) | VAF 106/258 reads (41%) | catalogued as rs780955219, COSV100546590, COSV61650841; called by muse, mutect2, varscan2
- TOGARAM2 | c.2322G>A p.L774= | Silent (SNP) | VAF 165/485 reads (34%) | called by muse, mutect2, varscan2
- TRAF3 | c.825C>T p.S275= | Silent (SNP) | VAF 49/165 reads (30%) | catalogued as rs758246898; called by muse, mutect2, varscan2
- TRPM4 | c.2157G>A p.R719= | Silent (SNP) | VAF 115/311 reads (37%) | called by muse, mutect2, varscan2
- VARS1 | c.2391C>T p.P797= | Silent (SNP) | VAF 185/754 reads (25%) | called by muse, mutect2, varscan2
- YARS1 | c.624C>T p.V208= | Silent (SNP) | VAF 73/287 reads (25%) | called by muse, mutect2, varscan2
- ZNF534 | c.1965C>T p.V655= (on ENST00000332323 / NM_001143939.3; = p.V642= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 120/365 reads (33%) | called by muse, mutect2, varscan2
- AC123912.1 | chr19:21553923 G>A | 3'Flank (SNP) | VAF 98/375 reads (26%) | called by muse, mutect2, varscan2
- C8orf86 | n.747G>A | RNA (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22568C>T | Intron (SNP) | VAF 68/198 reads (34%) | catalogued as rs1006337226, COSV52291480; called by muse, mutect2, varscan2
- CLIC5 | c.541-60272G>A | Intron (SNP) | VAF 121/488 reads (25%) | called by muse, mutect2, varscan2
- HES6 | c.251-20C>T | Intron (SNP) | VAF 135/442 reads (31%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4524G>A | Intron (SNP) | VAF 129/370 reads (35%) | called by muse, mutect2, varscan2
- NPAP1L | n.882C>T | RNA (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- PRUNE2 | c.756+35163G>A | Intron (SNP) | VAF 119/400 reads (30%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85663129 G>A | 5'Flank (SNP) | VAF 20/544 reads (4%) | called by muse, mutect2
- TERT | c.-57A>C | 5'UTR (SNP) | VAF 166/414 reads (40%) | catalogued as rs878855297, CR131339, COSV57196893; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.1118-753T>A | Intron (SNP) | VAF 103/291 reads (35%) | called by muse, mutect2, varscan2
- ZNF682 | c.*1G>A | 3'UTR (SNP) | VAF 28/187 reads (15%) | called by muse, mutect2, varscan2
